Gene-level copy-number profile of tumor specimen TCGA-37-A5EN-01A from TCGA case TCGA-37-A5EN, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 59.1 years (21,600 days).
Specimen TCGA-37-A5EN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.a5b23d65-42e6-4be3-ac3b-8bb4d68aca0f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-37-A5EN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e9c7d907-e560-44e9-8d75-ec29d4319c5c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 122; copy number 1: 239; copy number 2: 20,401; copy number 3: 16,679; copy number 4: 13,749; copy number 5: 5,897; copy number 6: 264; copy number 7: 1,435; copy number 8: 86; copy number 9: 184; copy number 10: 202; copy number 11: 37; copy number 12: 191; copy number 14: 10; copy number 15: 150; copy number 16: 119; copy number 21: 9; copy number 22: 23; copy number 43: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-37-A5EN-01A-21D-A26L-01): tumor purity 0.54, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,999,509–24,088,051, 71 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,624 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:94,650,544–94,651,378, 1 gene, copy number 21: KATNBL1P2.
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr2:3,703,575–94,604,573, 1,577 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:62,796,124–65,053,439, 34 genes, copy number 7 (within-gene range 3–7): RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2.
- chr3:93,843,764–117,997,592, 327 genes, copy number 7–15 (within-gene range 3–15) (broad region; genes not listed).
- chr3:139,005,806–139,357,223, 1 gene, copy number 7 (within-gene range 3–7): MRPS22.
- chr3:139,042,102–192,119,864, 848 genes, copy number 5–43 (broad region; genes not listed).
- chr3:192,238,037–192,283,097, 1 gene, copy number 5: FGF12-AS1.
- chr4:38,758,791–39,399,248, 14 genes, copy number 5: RNA5SP158, TLR10, TLR1, TLR6, FAM114A1, MIR574, TMEM156, KLHL5, AC079921.1, AC079921.2, WDR19, RFC1, RNU6-32P, RNU6-887P.
- chr4:39,411,910–39,411,974, 1 gene, copy number 5: MIR5591.
- chr6:38,923,029–44,553,281, 176 genes, copy number 6 (broad region; genes not listed).
- chr7:70,972–12,542,222, 238 genes, copy number 5 (broad region; genes not listed).
- chr7:39,947,522–86,217,733, 835 genes, copy number 5 (broad region; genes not listed).
- chr8:33,604,856–34,039,104, 1 gene, copy number 9 (within-gene range 3–9): AF279873.3.
- chr8:33,715,784–43,220,809, 183 genes, copy number 9 (broad region; genes not listed).
- chr8:109,240,919–110,105,964, 14 genes, copy number 5: NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48.
- chr9:24,542,952–43,045,120, 437 genes, copy number 5–15 (broad region; genes not listed).
- chr11:32,435,518–33,674,102, 28 genes, copy number 5 (within-gene range 4–5): WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4, EIF3M, HNRNPA3P9, CCDC73, AL049714.1, PRRG4, QSER1, Y_RNA, DEPDC7, TCP11L1, PIGCP1, LINC00294, CSTF3, CSTF3-DT, Y_RNA, RPL29P23, Y_RNA, AL136126.1, HIPK3, KIAA1549L, AL137161.1, AL133399.1.
- chr12:17,479,446–24,775,565, 88 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:31,382,226–31,591,136, 1 gene, copy number 11 (within-gene range 2–11): DENND5B.
- chr12:31,443,792–32,383,633, 36 genes, copy number 11: AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2.
- chr14:50,312,324–53,157,528, 79 genes, copy number 6 (broad region; genes not listed).
- chr16:58,157,907–60,928,541, 43 genes, copy number 5 (within-gene range 4–5): CSNK2A2, AC009107.1, RN7SL645P, CCDC113, PRSS54, GINS3, RNU6-269P, AC009118.1, RNU6-1110P, AC009118.2, LINC02137, NDRG4, RNU6-103P, SETD6, CNOT1, AC009118.3, SNORA46, SNORA50A, SNORA50A, AC010287.1, SLC38A7, AC012183.1, GOT2, AC106793.1, RNU6-1155P, RN7SL143P, GEMIN8P2, RPL12P36, AC092378.1, Metazoa_SRP, RPS27P27, AC092121.1, RNU4-58P, DUXAP11, APOOP5, LINC02141, AC009094.1, AC009081.2, AC018554.1, NPAP1L, AC009081.1, GNPATP, AC009169.1.
- chr16:64,155,169–68,477,570, 154 genes, copy number 5 (broad region; genes not listed).
- chr19:11,505,929–18,000,080, 378 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr19:30,219,666–38,975,742, 337 genes, copy number 5–16 (broad region; genes not listed).
- chr19:55,891,699–58,605,223, 188 genes, copy number 10–21 (within-gene range 2–21) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
